Somatic mutation profile of tumor specimen MP2PRT-PASYDS-TMP1-A (aliquot MP2PRT-PASYDS-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASYDS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,083 days).
Specimen MP2PRT-PASYDS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27abf4e4-fceb-479b-bbdf-5c22a9104027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYDS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYDS-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2946e66a-3c8e-4d46-b06e-c0115d1274e6

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 36/274 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LCA5 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 90/406 reads (22%) | catalogued as rs748370008, CM076260; ClinVar: pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 105/418 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs925829954; called by muse, mutect2
- CEP350 | c.3611G>A p.R1204H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV62603410; called by muse, mutect2, varscan2
- CLCNKA | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 250/558 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs574988239; called by muse, mutect2, varscan2
- CLIC6 | c.1504G>A p.V502I (on ENST00000360731 / NM_001317009.2; = p.V484I on NM_053277.3) | Missense Mutation (SNP) | VAF 88/437 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142788359; called by muse, mutect2, varscan2
- DNAH14 | c.5047C>T p.R1683C (on ENST00000445597; = p.R2088C on NM_001367479.1) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1052884266, COSV70531277; called by muse, mutect2, varscan2
- EDNRA | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 186/431 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs761439706; called by muse, mutect2, varscan2
- HOXA6 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 113/402 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1436047428; called by muse, mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 200/1450 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, mutect2, varscan2
- PCSK1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.62); catalogued as rs758046584, COSV60733679; called by muse, varscan2
- PIP4K2C | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs144510690; called by muse, mutect2, varscan2
- ROPN1B | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 68/413 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs929066469; called by muse, mutect2, varscan2
- SERPINB4 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs764188105, COSV61984169; called by muse, mutect2, varscan2
- TRPC4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs770123359; called by muse, mutect2, varscan2
- BCAT1 | c.367dup p.S123Ffs*11 | Frame Shift Ins (INS) | VAF 53/235 reads (23%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGEA1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 79/800 reads (10%) | called by muse, mutect2
- P2RY2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 236/558 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- SLFN13 | c.938del p.V313Gfs*4 | Frame Shift Del (DEL) | VAF 64/374 reads (17%) | called by mutect2, pindel, varscan2
- SPOCK1 | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ADAMTS17 | c.90C>T p.D30= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- CEP290 | c.2977T>C p.L993= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- COL8A1 | c.1239A>G p.K413= | Silent (SNP) | VAF 74/480 reads (15%) | catalogued as rs1261778141; called by muse, mutect2, varscan2
- SMIM23 | c.96C>T p.D32= | Silent (SNP) | VAF 216/477 reads (45%) | catalogued as rs540155693, COSV58353253; called by muse, mutect2, varscan2
- C14orf177 | n.508G>A | RNA (SNP) | VAF 264/800 reads (33%) | catalogued as rs759775875, COSV100362743; called by muse, mutect2, varscan2
- FAM182B | n.736G>A | RNA (SNP) | VAF 184/1332 reads (14%) | catalogued as rs1371973294; called by muse, varscan2
